Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96P, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96P-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

Tumor: 8.0 x 7.5 x 5.0 cm

Diagnosis:

Type B1-Thymoma

pT1

Masaoka: I

Immunohistochemistry

epithelial cells positive for: CK 5/6

CD3-, TdT-positive lymphocytes, negative staining for CD20, CK18, CD117

ICD-0.3
Thymoma, type B
malignant 8583/3
Site Anterior mediastinum
(38.1)
Q 4/14/14

Source: NCI Genomic Data Commons file 22a17c29-4a85-4649-913d-4568a4f09f05 (TCGA-ZB-A96P.B5E9D93F-F53A-45A6-9C88-AFE898DDE746.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).